Somatic mutation profile of tumor specimen TCGA-D8-A1J9-01A (aliquot TCGA-D8-A1J9-01A-11D-A13L-09) from TCGA case TCGA-D8-A1J9, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 49.0 years (17,879 days).
Specimen TCGA-D8-A1J9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58ae7bc8-34a1-4444-aab0-3164806e4514.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1J9-10A (Blood Derived Normal), aliquot TCGA-D8-A1J9-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93860d43-8c62-4925-93ae-443dc22a43e3

The open-access MAF lists 205 somatic variants for this specimen: 147 protein-altering or splice-affecting, 54 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 54, Nonsense Mutation 15, Intron 3, Splice Region 2, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRHL3 | c.1225C>T p.R409C (on ENST00000350501 / NM_198174.3; = p.R414C on NM_021180.3) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs770938921, COSV52565202, COSV99359152; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- JAG1 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 65/132 reads (49%) | catalogued as rs863223678, COSV54762876; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB6 | c.1070C>G p.S357* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV54700668; called by muse, mutect2, varscan2
- ABCB6 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV54700689; called by muse, mutect2, varscan2
- ACSF2 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs770288175, COSV51957311; called by muse, mutect2, varscan2
- ADGRV1 | c.6361C>T p.Q2121* | Nonsense Mutation (SNP) | VAF 36/108 reads (33%) | catalogued as COSV67995373; called by muse, mutect2, varscan2
- ALDH1L2 | c.1747G>C p.E583Q | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51559779, COSV99033622; called by muse, mutect2, varscan2
- AMBN | c.767G>C p.R256T | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59828142; called by muse, mutect2, varscan2
- ANKRD26 | c.1170G>T p.L390F | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as COSV101066613, COSV101066655; called by muse, mutect2
- ANTXR2 | c.1160G>T p.G387V | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100226973; called by muse, mutect2
- ARHGEF39 | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.268); catalogued as COSV100526368; called by muse, mutect2
- ATF7IP | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as COSV53777732; called by muse, mutect2, varscan2
- ATM | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.575); catalogued as CM116245, COSV53774785; called by muse, mutect2, varscan2
- BAIAP2L1 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs140166928; called by muse, mutect2, varscan2
- BCAP31 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV54386860; called by muse, mutect2, varscan2
- BCAS2 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.048); catalogued as COSV101058643, COSV65767466; called by muse, mutect2, varscan2
- BCL2L11 | c.458G>C p.R153P (on ENST00000393256 / NM_138621.5; = p.R93P on NM_006538.5) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58028974, COSV58030472; called by muse, mutect2, varscan2
- BNC1 | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV61759174; called by muse, mutect2, varscan2
- BOLA1 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV64967597; called by muse, varscan2
- BTN3A3 | c.1404G>C p.E468D | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV55073809; called by muse, mutect2, varscan2
- CALD1 | c.2026G>C p.D676H (on ENST00000361675 / NM_033138.4; = p.D421H on NM_004342.7) | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62653913; called by muse, mutect2, varscan2
- CATSPERB | c.2347G>A p.D783N | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV56435261; called by muse, mutect2, varscan2
- CCDC87 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as rs762394264, COSV59579483, COSV59579788; called by muse, mutect2, varscan2
- CCS | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59580569; called by muse, mutect2, varscan2
- CCT4 | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.924); catalogued as rs780164717, COSV66702082; called by muse, mutect2, varscan2
- CD3G | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52676236; called by muse, mutect2, varscan2
- CDH16 | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 24/48 reads (50%) | catalogued as COSV55339697; called by muse, mutect2, varscan2
- CDRT1 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.195); catalogued as rs771153280, COSV99887926; called by muse, mutect2, varscan2
- CHTF18 | c.1909C>A p.H637N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV50210997; called by muse, mutect2, varscan2
- CNST | c.1023G>C p.Q341H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV63622458; called by muse, mutect2, varscan2
- CNTN5 | c.1694C>T p.S565L | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as rs368554933; called by muse, mutect2, varscan2
- CWC25 | c.636G>T p.K212N | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs1254679236; called by muse, varscan2
- CYP2E1 | c.94C>G p.L32V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CX135018, COSV53315358; called by muse, mutect2, varscan2
- DDX21 | c.1161G>C p.K387N | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV100826551; called by muse, mutect2
- DEPDC4 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV54553890, COSV54554397; called by muse, mutect2, varscan2
- DMD | c.5476G>T p.E1826* | Nonsense Mutation (SNP) | VAF 13/185 reads (7%) | catalogued as CM096756, COSV63782395; called by muse, mutect2
- DRG2 | c.215C>G p.S72C | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56729496; called by muse, mutect2, varscan2
- ECM2 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV60742935; called by muse, mutect2, varscan2
- ELP3 | c.673G>C p.D225H | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99834227; called by muse, mutect2
- EPHX3 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs374205173; called by muse, mutect2, varscan2
- FAM9A | c.439A>G p.K147E | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.261); catalogued as COSV101121373; called by muse, mutect2
- FANCA | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.468); catalogued as COSV66881337, COSV66883840, COSV66883883; called by muse, mutect2, varscan2
- GALNT8 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52901736; called by muse, mutect2, varscan2
- GBP4 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV63255801, COSV63256031; called by muse, mutect2, varscan2
- GID4 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52010270; called by muse, varscan2
- GPR149 | c.1931C>G p.S644C | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67670052; called by muse, mutect2, varscan2
- GRB7 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 61/411 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV58450933; called by muse, mutect2, varscan2
- GRIN2A | c.1572C>G p.F524L | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV58056815; called by muse, mutect2, varscan2
- GRIN2B | c.4021G>C p.E1341Q | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.707); catalogued as COSV101663191, COSV74206579; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1989G>C p.Q663H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as rs781857495, COSV57032676; called by muse, mutect2, varscan2
- HERC1 | c.8376G>A p.M2792I | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV71250243; called by muse, mutect2, varscan2
- HMCES | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV59116509; called by muse, mutect2, varscan2
- HMCES | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV67300967; called by muse, mutect2, varscan2
- HMGB3 | c.535A>T p.K179* | Nonsense Mutation (SNP) | VAF 17/129 reads (13%) | catalogued as COSV57487320; called by muse, mutect2, varscan2
- HMGXB4 | c.1010A>G p.K337R | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV53335969; called by muse, mutect2, varscan2
- HOXA6 | c.528C>G p.F176L | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as rs750134271, COSV56072377, COSV56074833; called by muse, mutect2, varscan2
- HTR1A | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60502930; called by muse, mutect2, varscan2
- INF2 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV53032154, COSV53036503; called by muse, mutect2, varscan2
- INHBB | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as rs148176831; called by muse, mutect2, varscan2
- JAK3 | c.1467G>C p.Q489H | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV71687750; called by muse, mutect2, varscan2
- KCNE4 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99919144; called by muse, mutect2
- KIF13A | c.4297A>G p.R1433G | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV52465588; called by muse, mutect2, varscan2
- KLK10 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100011300; called by muse, mutect2, varscan2
- KRTAP10-4 | c.857C>G p.S286C | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782365750, COSV59979932; called by muse, mutect2, varscan2
- LILRB5 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs760247858, COSV60256329; called by muse, mutect2, varscan2
- LRP6 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99744551; called by muse, mutect2
- LY75 | c.4580C>G p.S1527* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as rs1308449239, COSV55113068; called by muse, mutect2, varscan2
- MACF1 | c.12080C>G p.S4027* (on ENST00000372915; = p.S1960* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV57120241, COSV57143958; called by muse, mutect2, varscan2
- MAGEA3 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV64755913; called by muse, mutect2, varscan2
- MARCHF7 | c.1903G>C p.E635Q | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52031443; called by muse, mutect2, varscan2
- MARVELD2 | c.1418C>G p.S473C | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100347956; called by muse, mutect2, varscan2
- MAST4 | c.1102G>A p.E368K (on ENST00000403625 / NM_001164664.2; = p.E179K on NM_015183.3) | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55141688; called by muse, mutect2, varscan2
- MBD6 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.019); catalogued as rs746957309, COSV63073749; called by muse, mutect2, varscan2
- MCOLN3 | c.385G>C p.A129P | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs142799067, COSV62016022; called by muse, mutect2, varscan2
- MED27 | c.812G>T p.R271I | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV52606388; called by muse, mutect2, varscan2
- MERTK | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.903); catalogued as COSV99775344; called by muse, mutect2
- MSH2 | c.1530G>C p.Q510H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs587782355, COSV51884914; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7B | c.3999G>A p.G1333= | Splice Region (SNP) | VAF 16/42 reads (38%) | catalogued as COSV52684501; called by muse, mutect2, varscan2
- NBEA | c.7007T>A p.L2336H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV100084399; called by muse, mutect2, varscan2
- NCKAP1L | c.1291C>G p.Q431E | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99515727; called by muse, mutect2
- NIN | c.4739C>T p.S1580L (on ENST00000382041 / NM_182946.1; = p.S867L on NM_016350.4) | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.069); catalogued as COSV55406237; called by muse, mutect2, varscan2
- NIN | c.1444C>A p.R482S | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55379762, COSV55406279; called by muse, mutect2, varscan2
- NINL | c.3877G>A p.E1293K | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV54008917; called by muse, varscan2
- NWD1 | c.772C>G p.H258D | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV60351687; called by muse, mutect2, varscan2
- OR7C1 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.308); catalogued as COSV99934967; called by muse, mutect2
- P2RX7 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 9/157 reads (6%) | catalogued as COSV99947813; called by muse, mutect2
- PAPLN | c.2498C>A p.A833E (on ENST00000554301; = p.A806E on NM_173462.4) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.026); catalogued as COSV53723791; called by muse, varscan2
- PARD6B | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65405274; called by muse, mutect2, varscan2
- PARP8 | c.788C>G p.S263C | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as COSV99892862; called by muse, mutect2, varscan2
- PBRM1 | c.4660G>C p.G1554R (on ENST00000296302 / NM_001366071.2; = p.G1447R on NM_018313.5) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.229); catalogued as COSV56303974, COSV99969577; called by muse, mutect2, varscan2
- PDCD11 | c.1531G>C p.D511H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as COSV63935347; called by muse, mutect2, varscan2
- PIKFYVE | c.3139C>G p.Q1047E | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV52249033; called by muse, mutect2, varscan2
- PLBD1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV53696033, COSV53696355; called by muse, mutect2, varscan2
- PLEKHH2 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 6/106 reads (6%) | catalogued as COSV99175116; called by muse, mutect2
- PSG4 | c.987C>T p.L329= | Splice Region (SNP) | VAF 87/198 reads (44%) | catalogued as COSV54940933; called by muse, mutect2, varscan2
- PTPRZ1 | c.1645C>G p.P549A | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.192); catalogued as COSV66445482; called by muse, mutect2, varscan2
- PWWP2B | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs773340929, COSV100535942, COSV100535962; called by muse, mutect2
- PYGL | c.2172G>C p.K724N | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV53588772; called by muse, mutect2, varscan2
- RAB11FIP4 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV57932904; called by muse, mutect2, varscan2
- RBAK | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT tolerated (0.32); PolyPhen benign (0.088); catalogued as COSV62332496; called by muse, mutect2, varscan2
- RFWD3 | c.1219C>G p.Q407E | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as COSV100736161, COSV63099402; called by muse, mutect2, varscan2
- RNF14 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.122); catalogued as COSV61662654; called by muse, mutect2
- RPL19 | c.24G>C p.K8N | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99841574; called by muse, mutect2
- SDR42E1 | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs1261282355, COSV100200749, COSV61095104; called by muse, mutect2, varscan2
- SETD1A | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.173); catalogued as rs1310642754, COSV52692443; called by muse, mutect2, varscan2
- SH2D7 | c.480G>C p.Q160H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV100174839; called by muse, mutect2
- SHMT2 | c.799C>G p.P267A | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100197414; called by muse, mutect2
- SLC2A10 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs776700297, COSV63716030; called by muse, mutect2, varscan2
- SLC5A11 | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV61743693; called by muse, mutect2, varscan2
- SLC9A8 | c.987C>G p.I329M | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV64291354; called by muse, mutect2, varscan2
- SLCO1B3 | c.1442A>T p.Y481F | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53946355; called by muse, mutect2, varscan2
- SMC1B | c.1570C>A p.H524N | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV62531913, COSV62533388; called by muse, mutect2, varscan2
- ST8SIA6 | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.054); catalogued as COSV101112233; called by muse, mutect2
- STAU1 | c.382C>G p.Q128E (on ENST00000371856 / NM_001319135.1; = p.Q47E on NM_004602.3) | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.193); catalogued as COSV61462569; called by muse, mutect2, varscan2
- SUMO1 | c.149C>A p.S50* | Nonsense Mutation (SNP) | VAF 49/183 reads (27%) | catalogued as COSV66260298, COSV66260948; called by muse, mutect2, varscan2
- SUPT6H | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.905); catalogued as rs897919382, COSV58924533; called by muse, mutect2, varscan2
- TASOR | c.1609C>T p.Q537* (on ENST00000355628 / NM_001365636.2; = p.Q141* on NM_015224.3) | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | catalogued as COSV62928736, COSV62929710; called by muse, mutect2, varscan2
- TBC1D10B | c.1926C>G p.I642M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.947); catalogued as rs779953424, COSV59769868; called by muse, mutect2, varscan2
- TDRD1 | c.3203C>G p.S1068C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52589014, COSV52596061; called by muse, mutect2, varscan2
- THSD7B | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.993); catalogued as COSV55737299; called by muse, mutect2, varscan2
- TRAF5 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV54824797; called by muse, mutect2, varscan2
- TRPM6 | c.3009G>T p.E1003D | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV62522304; called by muse, mutect2, varscan2
- TSPYL2 | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV64921522; called by muse, mutect2, varscan2
- TTN | c.49132G>A p.E16378K (on ENST00000591111; = p.E8954K on NM_003319.4) | Missense Mutation (SNP) | VAF 55/139 reads (40%) | PolyPhen benign (0.024); catalogued as rs758449770, COSV60342487; called by muse, mutect2, varscan2
- TUT7 | c.4246C>G p.Q1416E | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV52893173, COSV52898931; called by muse, mutect2, varscan2
- TXLNB | c.1110C>G p.F370L | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV64445685; called by muse, mutect2, varscan2
- UBAP2L | c.2999C>T p.S1000F | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV55169559, COSV55181071; called by muse, mutect2, varscan2
- USE1 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV55728851; called by muse, mutect2, varscan2
- USP6 | c.2062C>T p.Q688* | Nonsense Mutation (SNP) | VAF 14/136 reads (10%) | catalogued as rs1450211995, COSV51485370, COSV51496246; called by muse, mutect2, varscan2
- WNK4 | c.3380G>A p.S1127N | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV55910537; called by muse, mutect2, varscan2
- XIRP2 | c.7789C>T p.Q2597* (on ENST00000628543; = p.Q2772* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV54733830; called by muse, mutect2, varscan2
- ZBBX | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV56801421; called by muse, mutect2, varscan2
- ZC3H13 | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs550536100, COSV99668954; called by muse, mutect2
- ZFAND3 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV54723396; called by muse, mutect2
- ZKSCAN2 | c.63G>A p.M21I | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs1293922211, COSV100048567; called by muse, mutect2
- ZNF250 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as COSV99481086; called by muse, mutect2
- ZNF334 | c.870G>C p.E290D | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV61620143; called by muse, mutect2, varscan2
- ZNF460 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64416445; called by muse, mutect2, varscan2
- ZNF470 | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.239); catalogued as COSV100401062, COSV100401414; called by muse, mutect2
- ZNF532 | c.1564G>T p.V522L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV60175642; called by muse, mutect2, varscan2
- ZSWIM8 | c.3578C>T p.S1193L (on ENST00000605216 / NM_001242487.2; = p.S1198L on NM_015037.3) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV55217890; called by muse, mutect2, varscan2
- ACACA | c.3117G>C p.Q1039H | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- APH1B | c.62_63del p.Y21Cfs*40 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | called by mutect2, pindel, varscan2
- CSF1R | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2
- PCDHB9 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.341); called by muse, mutect2
- SLC26A11 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGEF39 | c.912C>T p.F304= | Silent (SNP) | VAF 26/316 reads (8%) | catalogued as COSV100526366; called by muse, mutect2
- ARPC5 | c.249C>T p.L83= | Silent (SNP) | VAF 31/134 reads (23%) | catalogued as rs1474783186, COSV54172597; called by muse, mutect2, varscan2
- CCT4 | c.333C>T p.I111= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as COSV66702088; called by muse, mutect2, varscan2
- CLIP1 | c.2319C>G p.L773= (on ENST00000620786 / NM_001247997.1; = p.L762= on NM_002956.2) | Silent (SNP) | VAF 63/167 reads (38%) | catalogued as COSV56808525; called by muse, mutect2, varscan2
- COL6A1 | c.360C>G p.V120= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100720472; called by muse, mutect2
- COLGALT2 | c.1035C>T p.F345= | Silent (SNP) | VAF 60/141 reads (43%) | catalogued as COSV62299518; called by muse, mutect2, varscan2
- COQ8A | c.93C>T p.G31= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV64659306; called by muse, mutect2, varscan2
- CYP2A13 | c.354C>T p.F118= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV57840105; called by muse, mutect2, varscan2
- CYP2A7 | c.45G>A p.L15= | Silent (SNP) | VAF 45/114 reads (39%) | catalogued as COSV52506483; called by muse, mutect2, varscan2
- DDR1 | c.1815C>T p.F605= (on ENST00000324771; = p.F568= on NM_001954.4) | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV61321355; called by muse, mutect2, varscan2
- DDR2 | c.726C>T p.F242= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV63374409; called by muse, mutect2, varscan2
- DPF2 | c.975C>T p.I325= | Silent (SNP) | VAF 41/144 reads (28%) | catalogued as COSV52891376; called by muse, mutect2, varscan2
- DSE | c.2109C>A p.A703= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV59067349; called by muse, mutect2, varscan2
- ERI3 | c.114G>A p.P38= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs1326133585, COSV100952160, COSV64833674; called by muse, mutect2
- FCRL3 | c.1500G>C p.L500= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100943439, COSV63844942; called by muse, mutect2, varscan2
- FCSK | c.3174C>T p.I1058= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as rs748424264, COSV55375477; called by muse, varscan2
- GAPVD1 | c.2151A>G p.V717= | Silent (SNP) | VAF 12/240 reads (5%) | catalogued as COSV99782533, COSV99783826; called by muse, mutect2
- GMEB2 | c.567G>A p.L189= | Silent (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- GPR39 | c.1179C>G p.L393= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV61417592; called by muse, mutect2, varscan2
- H2AC17 | c.282C>T p.L94= | Silent (SNP) | VAF 62/191 reads (32%) | catalogued as COSV58154029; called by muse, mutect2, varscan2
- H2BC18 | c.60G>A p.T20= | Silent (SNP) | VAF 17/252 reads (7%) | catalogued as rs782399861, COSV100516183, COSV58944534; called by muse, mutect2
- HEATR5B | c.2142C>T p.L714= | Silent (SNP) | VAF 58/190 reads (31%) | catalogued as COSV51859104; called by muse, mutect2, varscan2
- HES4 | c.267G>C p.R89= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV59243061; called by muse, mutect2, varscan2
- HTT | c.4428G>A p.L1476= | Silent (SNP) | VAF 80/275 reads (29%) | catalogued as COSV61869160, COSV61870819; called by muse, mutect2, varscan2
- IFT140 | c.3744C>T p.I1248= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV100794235, COSV63699249; called by muse, mutect2, varscan2
- IGKV3-15 | c.279C>G p.L93= | Silent (SNP) | VAF 56/314 reads (18%) | called by muse, mutect2, varscan2
- KRT19 | c.735C>T p.L245= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as rs148175649; called by muse, mutect2, varscan2
- LHX9 | c.1008A>G p.K336= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as COSV61331521; called by muse, mutect2, varscan2
- MAPK4 | c.1161G>A p.A387= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV68543576, COSV68543826; called by muse, mutect2, varscan2
- MUC16 | c.42222G>A p.L14074= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as COSV66696448; called by muse, mutect2, varscan2
- NCAM2 | c.669G>A p.E223= | Silent (SNP) | VAF 10/139 reads (7%) | catalogued as COSV99520917, COSV99525396; called by muse, mutect2
- NINL | c.3429G>A p.Q1143= | Silent (SNP) | VAF 28/47 reads (60%) | catalogued as COSV54004735, COSV54008927; called by muse, mutect2, varscan2
- NSMCE1 | c.579C>T p.I193= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV53731917; called by muse, mutect2, varscan2
- NUDT17 | c.438G>A p.E146= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV57908641; called by muse, mutect2, varscan2
- OR5H14 | c.564T>C p.S188= | Silent (SNP) | VAF 71/203 reads (35%) | catalogued as COSV101454332, COSV71194546; called by muse, mutect2, varscan2
- SCN8A | c.675G>A p.L225= | Silent (SNP) | VAF 67/190 reads (35%) | catalogued as rs1161949273, COSV61992996; called by muse, mutect2, varscan2
- SIGLEC6 | c.1002C>A p.L334= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV100585831, COSV58433907, COSV58437460; called by muse, mutect2, varscan2
- SLITRK3 | c.534G>A p.L178= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV53853384; called by muse, mutect2, varscan2
- SOAT1 | c.663C>A p.L221= | Silent (SNP) | VAF 66/211 reads (31%) | catalogued as COSV62654083, COSV62656873; called by muse, mutect2, varscan2
- STAC | c.234G>A p.E78= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV56213946, COSV56218118; called by muse, mutect2, varscan2
- SYNE1 | c.153C>T p.D51= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs779081280, COSV55100780; called by muse, mutect2, varscan2
- TAF1L | c.4086C>G p.L1362= | Silent (SNP) | VAF 60/115 reads (52%) | catalogued as COSV54269155; called by muse, mutect2, varscan2
- TBX5 | c.822C>T p.F274= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV59860562; called by muse, mutect2
- TMEM132A | c.876G>A p.V292= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99137255; called by muse, mutect2
- TNFAIP6 | c.654C>A p.I218= | Silent (SNP) | VAF 52/136 reads (38%) | catalogued as COSV54642627; called by muse, mutect2, varscan2
- TOGARAM2 | c.1587G>A p.L529= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV65423906; called by muse, mutect2, varscan2
- TUBGCP6 | c.1575G>A p.L525= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV50584573; called by muse, mutect2, varscan2
- UBE4B | c.1764C>G p.L588= (on ENST00000343090 / NM_001105562.3; = p.L459= on NM_006048.5) | Silent (SNP) | VAF 50/146 reads (34%) | catalogued as rs777413135, COSV53542299; called by muse, mutect2, varscan2
- UBN1 | c.417C>T p.I139= | Silent (SNP) | VAF 10/127 reads (8%) | catalogued as rs750592271, COSV99278662; called by muse, mutect2
- URB2 | c.411C>T p.V137= | Silent (SNP) | VAF 34/61 reads (56%) | catalogued as COSV51045433; called by muse, mutect2, varscan2
- WDPCP | c.915C>T p.S305= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs370372057; ClinVar: likely benign; called by muse, mutect2, varscan2
- WDR64 | c.1146C>G p.V382= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV100843925, COSV63794001, COSV63800526; called by muse, mutect2, varscan2
- ZNF227 | c.1560C>T p.F520= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as rs1568619861, COSV57312770; called by muse, mutect2
- ZNF564 | c.252C>T p.F84= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV59436507; called by muse, mutect2, varscan2
- SSX6P | chrX:48117135 C>T | 3'Flank (SNP) | VAF 44/108 reads (41%) | called by muse, mutect2, varscan2
- STAG2 | c.3467+150G>A | Intron (SNP) | VAF 9/140 reads (6%) | catalogued as rs1356742526, COSV99495475; called by muse, mutect2
- TPD52 | c.507-1520C>G | Intron (SNP) | VAF 38/112 reads (34%) | catalogued as COSV66951892; called by muse, mutect2, varscan2
- TTN | c.10360+4468C>G | Intron (SNP) | VAF 59/130 reads (45%) | catalogued as COSV59994749; called by muse, mutect2, varscan2
